Somatic mutation profile of tumor specimen 1105202 (aliquot 7316UP-1108-1105202) from CPTAC case C383391, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Temporal lobe; Tumor grade: G3.
Specimen 1105202: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 576e7d22-88a5-4b3d-ad89-6c7a175f671f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105272 (Blood Derived Normal), aliquot 7316UP-1108-1105272; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/675054b0-be9f-4aba-9db6-fdf379808460

The open-access MAF lists 55 somatic variants for this specimen: 32 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 20, Nonsense Mutation 2, RNA 1, Intron 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAIN1 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.062); catalogued as rs745657091, COSV71420513; called by muse, mutect2, varscan2
- ARHGAP44 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs367607261; called by muse, mutect2, varscan2
- BMP10 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs144469983; called by muse, mutect2, varscan2
- CAMSAP3 | c.3101G>A p.R1034H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs888893073, COSV50331293; called by muse, mutect2
- CHAT | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 114/221 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs779668516, COSV60334873; called by muse, mutect2, varscan2
- COL6A5 | c.2644C>T p.R882W | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs374168010; called by muse, mutect2, varscan2
- DDX60 | c.2360C>T p.T787M | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1489149518; called by muse, mutect2, varscan2
- DPP9 | c.1618C>T p.R540C (on ENST00000598800; = p.R569C on NM_139159.5) | Missense Mutation (SNP) | VAF 40/369 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as rs202052088; called by muse, mutect2, varscan2
- FAT1 | c.7556G>A p.G2519E | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs550477464; called by muse, mutect2, varscan2
- FRMPD4 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 74/107 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66223539; called by muse, mutect2, varscan2
- KRTAP4-6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 187/544 reads (34%) | SIFT tolerated (0.13); catalogued as rs763253803, COSV61980902; called by muse, mutect2, varscan2
- MYOD1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51456293; called by muse, mutect2, varscan2
- PNKD | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs756863425, COSV51231403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTH2R | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as rs753279962, COSV55915312; called by muse, mutect2, varscan2
- RBFOX1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376377058; called by muse, varscan2
- RELN | c.9904G>A p.A3302T | Missense Mutation (SNP) | VAF 159/721 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs776769644, COSV59040921; called by muse, mutect2, varscan2
- RELN | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 168/641 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759711654, COSV59024775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3C | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as rs923497577, COSV67139620; called by muse, varscan2
- VAV2 | c.1351G>A p.E451K (on ENST00000371850 / NM_001134398.2; = p.E446K on NM_003371.4) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as rs755369467; called by muse, mutect2, varscan2
- XKR3 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 69/219 reads (32%) | catalogued as rs562118958; called by muse, mutect2
- CD96 | c.1480A>G p.T494A (on ENST00000283285 / NM_198196.3; = p.T478A on NM_005816.5) | Missense Mutation (SNP) | VAF 123/402 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CLEC4G | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CREBBP | c.3197G>A p.S1066N | Missense Mutation (SNP) | VAF 112/293 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRTC2 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 164/514 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by mutect2, varscan2
- CRYBG1 | c.3650C>A p.P1217Q | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DLC1 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by mutect2, varscan2
- GOLGA7 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- MYH13 | c.2028T>A p.C676* | Nonsense Mutation (SNP) | VAF 42/155 reads (27%) | called by muse, mutect2, varscan2
- NOBOX | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 89/326 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THADA | c.2371C>A p.L791I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TMEM132C | c.2708A>G p.K903R | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YTHDF3 | c.98dup p.D33Efs*2 | Frame Shift Ins (INS) | VAF 46/167 reads (28%) | called by mutect2, pindel, varscan2
- ADAM29 | c.612C>T p.V204= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as rs114696296, COSV63668865; called by muse, mutect2, varscan2
- ARID1A | c.6057C>T p.H2019= | Silent (SNP) | VAF 110/294 reads (37%) | called by muse, mutect2, varscan2
- ARPC4 | c.114G>A p.V38= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as rs1482592313; called by muse, mutect2, varscan2
- CHRM2 | c.117C>T p.I39= | Silent (SNP) | VAF 140/499 reads (28%) | catalogued as rs755854009, COSV57773475; called by muse, mutect2, varscan2
- CLSTN2 | c.2004C>T p.F668= | Silent (SNP) | VAF 89/258 reads (34%) | catalogued as rs778778245, COSV71720462; called by muse, mutect2, varscan2
- DLC1 | c.2967G>T p.G989= (on ENST00000276297 / NM_001348081.2; = p.G552= on NM_006094.5) | Silent (SNP) | VAF 70/162 reads (43%) | catalogued as rs1563589459; called by muse, varscan2
- DPYSL2 | c.645G>T p.L215= | Silent (SNP) | VAF 94/289 reads (33%) | called by muse, mutect2, varscan2
- MYH7 | c.4740C>T p.D1580= | Silent (SNP) | VAF 104/258 reads (40%) | catalogued as rs201469051, COSV62516883; called by muse, mutect2, varscan2
- NDRG4 | c.654G>A p.T218= (on ENST00000570248 / NM_001378344.1; = p.T250= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 59/180 reads (33%) | catalogued as rs781381338, COSV99262394; called by muse, mutect2, varscan2
- OR2AK2 | c.99C>G p.T33= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV63554593; called by muse, mutect2, varscan2
- OR5AU1 | c.267G>A p.R89= | Silent (SNP) | VAF 139/391 reads (36%) | catalogued as rs779575360; called by muse, mutect2, varscan2
- PRDM16 | c.2667G>A p.P889= | Silent (SNP) | VAF 45/146 reads (31%) | catalogued as rs774537766; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC30A3 | c.933G>A p.S311= | Silent (SNP) | VAF 95/299 reads (32%) | catalogued as rs538009364, COSV99273777, COSV99273918; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A14 | c.726G>A p.A242= | Silent (SNP) | VAF 101/250 reads (40%) | catalogued as rs752901596, COSV51580118; called by muse, mutect2, varscan2
- SV2C | c.1647A>G p.P549= | Silent (SNP) | VAF 53/141 reads (38%) | called by muse, mutect2, varscan2
- TANC1 | c.600C>T p.S200= | Silent (SNP) | VAF 93/365 reads (25%) | catalogued as rs1362556739; called by muse, mutect2, varscan2
- TOP2A | c.927G>A p.Q309= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs1403734143; called by muse, mutect2, varscan2
- UNC13C | c.4164C>A p.V1388= | Silent (SNP) | VAF 51/176 reads (29%) | called by muse, mutect2, varscan2
- USH2A | c.6579C>T p.I2193= | Silent (SNP) | VAF 57/157 reads (36%) | catalogued as rs765566223; called by muse, mutect2, varscan2
- ZAN | c.4158C>T p.C1386= | Silent (SNP) | VAF 68/253 reads (27%) | catalogued as rs376999914; called by muse, mutect2, varscan2
- DUX4L8 | n.706C>T | RNA (SNP) | VAF 66/1009 reads (7%) | catalogued as rs782032535; called by muse, mutect2
- GABBR1 | c.476-60G>T | Intron (SNP) | VAF 109/302 reads (36%) | catalogued as rs1347490372; called by muse, mutect2, varscan2
- LILRA5 | c.-44T>A | 5'UTR (SNP) | VAF 44/140 reads (31%) | catalogued as rs1380637405; called by muse, mutect2, varscan2
